BEATAML1.0 case 2641 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/84ec4f88-5bfa-41ed-96f6-9f9aaadaa88c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Acute myelomonocytic leukemia: ICD-O-3 morphology code: 9867/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.1 years (23,783 days); Progression or recurrence: no.

Biospecimens (2 samples)
- Sample BA3207D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
- Sample BA3207R: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Fresh.
